Somatic mutation profile of tumor specimen TARGET-20-PASYCJ-09A (aliquot TARGET-20-PASYCJ-09A-01D) from TARGET case TARGET-20-PASYCJ, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,341 days).
Specimen TARGET-20-PASYCJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74a5302b-7b88-4205-92dc-8e79739976dd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASYCJ-14A (Bone Marrow Normal), aliquot TARGET-20-PASYCJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/588d6de0-07f1-43fc-a5ee-f678a62e4ca4

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 39/97 reads (40%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- TRIM24 | c.2981A>G p.E994G (on ENST00000343526 / NM_015905.3; = p.E960G on NM_003852.4) | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.122); called by muse, mutect2, varscan2
